Somatic mutation profile of tumor specimen TCGA-AC-A2B8-01A (aliquot TCGA-AC-A2B8-01A-11D-A17D-09) from TCGA case TCGA-AC-A2B8, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 84.9 years (31,003 days).
Specimen TCGA-AC-A2B8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1b5df85-dc18-4a7c-90b7-2a420dfbe18c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A2B8-10A (Blood Derived Normal), aliquot TCGA-AC-A2B8-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/981e9187-d815-47a1-999b-4d747b2af90f

The open-access MAF lists 101 somatic variants for this specimen: 74 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 26, Nonsense Mutation 4, In Frame Del 3, 5'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 28/53 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRG4 | c.8071G>C p.E2691Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.53); catalogued as COSV54957374; called by muse, mutect2, varscan2
- AKAP17A | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV58309952; called by muse, mutect2, varscan2
- ARHGAP29 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53112446; called by muse, mutect2, varscan2
- AVPR1A | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); catalogued as COSV54546905; called by muse, mutect2
- CKAP5 | c.5491G>A p.D1831N (on ENST00000529230 / NM_001008938.4; = p.D1771N on NM_014756.3) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV56368369; called by muse, mutect2, varscan2
- CLGN | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as rs1048681488, COSV57774925; called by muse, mutect2, varscan2
- CNDP1 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV62594012; called by muse, mutect2, varscan2
- COL19A1 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100505255; called by muse, mutect2
- CYFIP2 | c.3663G>C p.K1221N (on ENST00000616178 / NM_001291722.2; = p.K1196N on NM_014376.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.932); catalogued as COSV59039542; called by muse, mutect2, varscan2
- DEPDC7 | c.1138-1G>C p.X380_splice (on ENST00000241051 / NM_001077242.2; = p.X371_splice on NM_139160.2) | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as rs768013206, COSV53807419; called by muse, mutect2, varscan2
- DPP9 | c.921G>C p.R307S (on ENST00000598800; = p.R336S on NM_139159.5) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV53591597; called by muse, mutect2, varscan2
- EVC | c.2420G>C p.R807T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV53833266; called by muse, mutect2, varscan2
- FAM81A | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV55677954; called by muse, mutect2, varscan2
- FARP2 | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.484); catalogued as COSV50871896; called by muse, mutect2, varscan2
- FLG2 | c.2894G>C p.G965A | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as rs571867232, COSV66169127; called by muse, varscan2
- FLG2 | c.2832G>C p.Q944H | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV66169131, COSV66174444; called by muse, varscan2
- GJD2 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1160726049, COSV51748345; called by muse, mutect2
- H3C2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV52518070, COSV52519869; called by muse, mutect2
- HSPA5 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV61029267; called by muse, mutect2, varscan2
- HTT | c.6970G>A p.E2324K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV61862945; called by muse, mutect2, varscan2
- INA | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.878); catalogued as COSV100878574; called by muse, mutect2
- KNTC1 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV59204769; called by muse, mutect2, varscan2
- LDHA | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV57040400; called by muse, mutect2, varscan2
- LDLRAD1 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64956078; called by muse, mutect2, varscan2
- MAP3K5 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62888345, COSV62889421; called by muse, mutect2, varscan2
- MARS1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV56255250; called by muse, mutect2, varscan2
- MDP1 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99164593; called by muse, mutect2, varscan2
- MRTFB | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59118796; called by muse, mutect2, varscan2
- NEB | c.11512G>T p.D3838Y | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99415127; called by muse, mutect2, varscan2
- NSD1 | c.4211G>A p.R1404H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776547552, COSV61777002; called by muse, mutect2, varscan2
- NUDT1 | c.205G>A p.E69K (on ENST00000397048 / NM_198952.1; = p.E46K on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.847); catalogued as rs374666803; called by muse, mutect2, varscan2
- NUFIP1 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV64791262; called by muse, mutect2, varscan2
- OR10J1 | c.678G>C p.K226N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV71128916; called by muse, mutect2, varscan2
- PCDH15 | c.4898C>T p.S1633L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0.01); catalogued as COSV64698531; called by muse, mutect2, varscan2
- PCDHGA1 | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.314); catalogued as COSV65296832; called by muse, mutect2, varscan2
- PCF11 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as COSV53527390, COSV53531847; called by muse, mutect2, varscan2
- PCSK6 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as COSV59341276; called by muse, mutect2, varscan2
- PIP4P2 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV53438949; called by muse, mutect2, varscan2
- PJA2 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV63273041; called by muse, mutect2, varscan2
- POTEH | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100624692; called by muse, mutect2
- PSG8 | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.19); catalogued as rs779728700, COSV100126713, COSV60612200; called by muse, mutect2, varscan2
- RBL1 | c.1318C>G p.Q440E | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV60330196; called by muse, mutect2, varscan2
- RCC1L | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as rs781968660, COSV57320360; called by muse, mutect2, varscan2
- RFFL | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV52071905; called by muse, mutect2, varscan2
- RPL10 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV50010394; called by muse, mutect2, varscan2
- SETBP1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56323096; called by muse, mutect2, varscan2
- SF3B1 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59215175; called by muse, mutect2, varscan2
- SH3PXD2A | c.1217C>G p.S406C (on ENST00000369774 / NM_001365079.1; = p.S378C on NM_014631.2) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60117605; called by muse, mutect2, varscan2
- SMPD1 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs768566892, COSV54968367; called by muse, mutect2, varscan2
- STEAP1 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs753718544, COSV51881738; called by muse, mutect2, varscan2
- STXBP3 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64182317; called by muse, mutect2, varscan2
- SUPT20H | c.376G>A p.D126N (on ENST00000350612 / NM_001014286.3; = p.D127N on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV62248066; called by muse, mutect2, varscan2
- SYNE2 | c.9673G>A p.D3225N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV59952535, COSV59968284; called by muse, mutect2, varscan2
- TBX22 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV64786184, COSV64787233; called by muse, mutect2, varscan2
- TENM1 | c.6637G>T p.D2213Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64433130; called by muse, mutect2, varscan2
- TJP3 | c.1892C>G p.A631G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53662987; called by muse, mutect2, varscan2
- TMOD4 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as COSV54860896; called by muse, mutect2, varscan2
- TP53BP1 | c.5348G>C p.G1783A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53019396; called by muse, mutect2, varscan2
- TRIM65 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs765026510, COSV53933370; called by muse, mutect2, varscan2
- TRPV6 | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63891975; called by muse, mutect2, varscan2
- TSC2 | c.2828G>A p.R943K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as rs1447031509, COSV54766135; called by muse, mutect2, varscan2
- TTN | c.70328G>C p.R23443P (on ENST00000591111; = p.R16019P on NM_003319.4) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | PolyPhen possibly damaging (0.713); catalogued as COSV59915666, COSV60099677; called by muse, mutect2, varscan2
- TYW1 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV55887052; called by muse, mutect2, varscan2
- UBQLN3 | c.1685G>A p.R562K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.76); catalogued as COSV100293367; called by muse, mutect2
- WRN | c.2260C>G p.L754V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53300894; called by muse, mutect2, varscan2
- ZBTB40 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs929268647, COSV65145451; called by muse, mutect2
- ZMYM2 | c.1649_1650del p.Q550Lfs*5 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV67034548; called by mutect2, pindel, varscan2
- ZNF155 | c.372C>G p.F124L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV54206325, COSV54207029; called by muse, mutect2, varscan2
- ZNF592 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs974416295, COSV55436687; called by muse, varscan2
- ZP4 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs199993506; called by muse, mutect2, varscan2
- CDH1 | c.1806_1808del p.C603del | In Frame Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, pindel, varscan2
- ERN1 | c.1143_1154del p.N381_P384del | In Frame Del (DEL) | VAF 12/59 reads (20%) | called by pindel, varscan2*
- RANBP6 | c.1576_1584del p.S526_A528del | In Frame Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- ACTA1 | c.69C>T p.F23= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs1339913000, COSV64202957; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK18 | c.1491G>A p.K497= (on ENST00000506784 / NM_212503.3; = p.K467= on NM_002596.4) | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV63727650; called by muse, mutect2
- CSMD3 | c.3021G>A p.T1007= (on ENST00000297405 / NM_001363185.1; = p.T903= on NM_052900.3) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs761435780, COSV52194726; called by muse, mutect2, varscan2
- CYP7A1 | c.1514G>A p.*505= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV56963878; called by muse, mutect2, varscan2
- DHTKD1 | c.408A>G p.Q136= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1161663539, COSV53803963; called by muse, mutect2, varscan2
- DMXL2 | c.291C>G p.L97= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV51847400; called by muse, mutect2, varscan2
- EFCC1 | c.1488G>C p.L496= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV101460038, COSV71401865; called by muse, mutect2, varscan2
- ELK3 | c.948C>T p.L316= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57386682; called by muse, varscan2
- ELMO1 | c.621G>A p.S207= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs148167670; called by muse, mutect2, varscan2
- GIPC2 | c.387C>T p.L129= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV66128141; called by muse, mutect2, varscan2
- GRAMD1C | c.720C>T p.I240= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV63982865; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.315G>C p.L105= | Silent (SNP) | VAF 12/143 reads (8%) | called by muse, mutect2
- IGHV3-30 | c.144C>T p.F48= | Silent (SNP) | VAF 27/263 reads (10%) | catalogued as rs765088659; called by muse, mutect2
- LAMA5 | c.4419C>T p.T1473= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs377465022; called by muse, mutect2, varscan2
- LRRC18 | c.555G>A p.S185= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs376105556, COSV53282448; called by muse, mutect2, varscan2
- MAG | c.12C>T p.L4= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100728032, COSV62700832; called by muse, mutect2, varscan2
- MYO3A | c.1197G>A p.K399= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs762738257, COSV56333014; called by muse, mutect2, varscan2
- OR10H1 | c.6G>A p.Q2= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV58470619; called by muse, mutect2, varscan2
- OR4D11 | c.906G>A p.K302= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV57585725, COSV57585770; called by muse, mutect2, varscan2
- PBRM1 | c.2217T>C p.N739= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV56279207; called by muse, mutect2, varscan2
- RND1 | c.648C>T p.L216= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV59045368; called by muse, mutect2, varscan2
- SLC16A14 | c.1002C>T p.F334= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54618889; called by muse, mutect2, varscan2
- SLCO4C1 | c.322C>T p.L108= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV60516269; called by muse, mutect2, varscan2
- SPIDR | c.663G>A p.E221= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52378612; called by muse, mutect2, varscan2
- TTLL12 | c.1791G>A p.R597= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99333200; called by muse, mutect2
- ZNF558 | c.325C>T p.L109= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV56863374; called by muse, mutect2, varscan2
- NRROS | c.-1G>A | 5'UTR (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100145358; called by muse, mutect2, varscan2
